Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-AE6D, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-AE6D-TTP1-A (Primary Tumor).

[page 1 of 9]
+122

Pathology Report: SURGICAL LEVEL IV MINOR & MICRO,

SURGICAL LEVEL IV MINOR & MICRO,

Collect Date +0

Ordering Physician-

Attending Physician-

Referring Physician-

Primary Care Physician-

SPECIMEN #:

SPECIMEN(S):

A: ESOPHAGEAL BIOPSY, POLYP

B: COLON POLYP, ASCENDING

C: RECTAL BIOPSY / POLYPS

CLINICAL HISTORY

GI BLEED

FINAL PATHOLOGIC DIAGNOSIS

A. ESOPHAGUS, POLYP, BIOPSY: INVASIVE POORLY-DIFFERENTIATED
ADENOCARCINOMA WITH FOCAL ULCERATION

B. COLON POLYP, ASCENDING: TUBULAR ADENOMA

C. COLON, RECTAL POLYPS, BIOPSY: TUBULOVILLOUS ADENOMA

COMMENT

AN INTRADEPARTMENTAL CONSULTATION WAS PERFORMED FOR PART A.

ELECTRONICALLY SIGNED OUT

ADDENDUM

ADDENDUM DIAGNOSIS

{NOT ENTERED}

ADDENDUM COMMENT

SPECIMEN WAS REFERRED TO

FOR HER2/NEU BY IHC. RESULTS WERE REPORTED AS "EQUIVOCAL 2+".

ELECTRONICALLY SIGNED OUT

[page 2 of 9]
GROSS DESCRIPTION

SPECIMEN A IS LABELED "ESOPH POLYP" AND CONSISTS OF FRIABLE TAN-PINK SOFT TISSUE FRAGMENTS WHICH AGGREGATE 1.1 X 0.5 X 0.3CM AND ARE SUBMITTED EN TOTO.

SPECIMEN B IS LABELED "ASCEND COLON POLYP" AND CONSISTS OF THREE TAN-PINK SOFT TISSUES THAT AVERAGE 0.4CM AND ARE SUBMITTED EN TOTO.

SPECIMEN C IS LABELED "RECTAL POLYP" AND CONSISTS OF A 0.4CM TAN-PINK TISSUE POLYP. THE PRESUMED SITE OF ATTACHMENT IS INKED. ALL SUBMITTED.

PATIENT NAME:

MR #:

Electronically Signed by

[page 3 of 9]
+3

Imaging Report: NM TUM IMA PET W/CT COR/LOC WBOD

Provider:

Location:

NM TUM IMA PET W/CT COR/LOC WBOD,

Ordering Physician-

Attending Physician-

Referring Physician-

Primary Care Physician-

EXAM ROOM- CT PET ROOM

EXAM START- +3

EXAM STOP- +3

FILMS USED- NONE

REPORT- Interpretation follows +3

DATE/TIME OF DICTATION-

DICTATION LOCATION-

INDICATION- Esophageal tumor, initial treatment strategy.

COMPARISON- CT +1

TECHNIQUE- PET-CT from the top of the skull to the mid thighs following injection of 16.2 mCi of F-18 FDG and 80 mL of Omnipaque 300.

GLUCOSE- 51.

FINDINGS-

HEAD AND NECK- No hypermetabolic mass or adenopathy is identified.

LUNGS- No hypermetabolic lung nodule is identified. Calcified left upper lobe granuloma is present. There is no consolidation or pleural effusion.

CARDIOVASCULAR- Heart size is normal. There is no pericardial effusion. There is no aortic aneurysm.

LYMPHATICS- Hypermetabolic right superior mediastinal lymph node is present. Hypermetabolic celiac axis, periportal, pericaval, mesenteric, periaortic, bilateral common iliac chain and left external iliac chain lymph nodes are present. Spleen is unremarkable.

HEPATOBIILIARY- Hypermetabolic focus is seen within the region of the posterior right lobe of the liver (image of the fused axial series). This activity overlaps the liver and adjacent lung. No associated lung nodule is seen. More inferiorly within the liver on the CT images, there is an ill defined hypodensity (image series), which may correspond to the hypermetabolic activity. There are peripherally enhancing lesions within the liver dome and left lobe, which are non hypermetabolic and most likely represent hemangiomas. Gallbladder is completely collapsed. The pancreas is unremarkable.

[page 4 of 9]
GU- Mild hypermetabolic activity is seen within the left adrenal gland. There is no hydronephrosis. Bladder is decompressed. Prostate is mildly enlarged.

GI- There is intensely hypermetabolic wall thickening within the distal esophagus extending into the gastric cardia. There is no bowel obstruction. No free air or free fluid is seen. Mild haziness of the mesenteric and retroperitoneal fat is probably related to the adenopathy.

MUSCULOSKELETAL- Hypermetabolic lesion is seen within the L3 vertebral body.

IMPRESSION-

1. Hypermetabolic distal esophageal mass consistent with patient's known malignancy.
2. Hypermetabolic adenopathy within the chest, abdomen and pelvis, suspicious for metastatic disease.
3. Hypermetabolic liver lesion, suspicious for metastatic disease.
4. Hypermetabolic left adrenal lesion, suspicious for metastatic disease.
5. Hypermetabolic L3 lesion, suspicious for metastatic disease.

Transcriptionist-
Reading Radiologist
Releasing Radiologist
Released Date Time

CT Radiation Dose Reduction Techniques and ALARA (as low as reasonably achievable) Techniques are utilized where appropriate with all modalities utilizing ionizing and other radiation within our Department.

READ BY-
RELEASED

Electronically Signed by

[page 5 of 9]
+177

Imaging Report: CCP TUM IMG PET WCT COR SKU MIDTH, [REDACTED]

Provider: [REDACTED]

Location: [REDACTED]

CCP TUM IMG PET WCT COR SKU MIDTH, [REDACTED]

Ordering Physician- [REDACTED]

Attending Physician- [REDACTED]

Referring Physician- [REDACTED]

Primary Care Physician- [REDACTED]

EXAM ROOM- [REDACTED]

EXAM START- [REDACTED]

+176

EXAM STOP- [REDACTED]

+176

FILMS USED- NONE

REPORT- Interpretation follows

DATE/TIME OF DICTATION [REDACTED]

+176

DATE OF EXAMINATION- [REDACTED]

+176

DICTATION LOCATION- [REDACTED]

PET/CT

INDICATION- Subsequent treatment strategy, esophageal cancer.

COMPARISON- [REDACTED] +88

TECHNIQUE- PET/CT from the top of the skull to the mid thighs with 14.1 mCi of F18 FDG and 100 mL of Omnipaque 300. Glucose 91.

FINDINGS-

HEAD AND NECK- No hypermetabolic mass or adenopathy. Mucosal thickening is seen in the right maxillary sinus.

LUNGS- No hypermetabolic lung nodule. No consolidation or pleural effusion. Bibasilar atelectasis.

CARDIOVASCULAR- The heart size is borderline. There is no pericardial effusion. There is no aortic aneurysm.

LYMPHATICS- No hypermetabolic adenopathy is identified. The spleen is unremarkable.

HEPATOBIILIARY- Non-hypermetabolic hypodensity in the left lobe of the liver (image [REDACTED]) is unchanged and may be hemangioma. Previously described heterogeneous uptake in the lateral segment of the left lobe has resolved. There is a non-hypermetabolic hypodensity in the left lobe (image [REDACTED]) which may also be a hemangioma. Gallbladder and pancreas are unremarkable.

GU- The kidneys and adrenal glands are unremarkable. Mild diffuse bladder wall thickening may be related to outlet obstruction from a mildly enlarged prostate, similar to the prior study.

[page 6 of 9]
GI- No suspicious radiotracer uptake. No bowel obstruction or free fluid.

MUSCULOSKELETAL- No hypermetabolic bone lesion is identified. There is decreased sclerosis within the L3 vertebral body compared with the prior study. Endplate irregularity may represent a Schmorl's node or metastatic sequelae, unchanged.

IMPRESSION-

1. Interval resolution of hypermetabolic activity in the liver.
2. Decreased sclerosis within the L3 vertebral body.
3. No other significant change from the prior exam.

Transcriptionist-
Reading Radiologist
Releasing Radiologist
Released Date Time

CT Radiation Dose Reduction Techniques and ALARA (as low as reasonably achievable) Techniques are utilized where appropriate with all modalities utilizing ionizing and other radiation within our Department.

READ BY-
RELEASED

Electronically Signed by

[page 7 of 9]
[REDACTED]

Order

PET CT TUMOR IMAGING SKULL BASE TO MID THIGH

Study Status

Study Status: Final Read by: [REDACTED]

Study Result

PATIENT NAME: [REDACTED]

DOB: [REDACTED] -22277

DOCUMENT TYPE: RADIOLOGY

ORDER NUMBER/RESULT CODE ORDERING PHYSICIAN
[REDACTED]

DATE AND TIME OF DICTATION RADIOLOGIST
[REDACTED]

EXAM DESCRIPTION

PET CT TUMOR IMAGING SKULL BAS

HISTORY: A 63-year-old male with esophageal cancer and osseous metastases status post chemotherapy. Subsequent treatment strategy.

TECHNIQUE: PET/CT images from the skull base to the mid thighs were obtained following the administration of 15.9 mCi of F-18 FDG, as well as 100 mL of Omnipaque intravenous contrast according to a standard protocol. The patient's serum glucose level was 94 mg/dL.

COMPARISON: [REDACTED] +570

A dose lowering technique was used for this procedure, which may include, but is not limited to, dose reduction technique(s), automated exposure control technique(s), use of iterative reconstruction technique(s), and ALARA (as low as reasonably achievable) or ALARA/IMAGE Gently technique(s).

FINDINGS:

HEAD AND NECK:

CHEST: There is an air/fluid level in the right maxillary sinus, which is unchanged. No head and neck lymphadenopathy. The thyroid gland is normal. No hypermetabolic lesions are seen.

CHEST:

CARDIOVASCULAR: A port catheter tip terminates in the superior vena cava. The heart size is normal. No pericardial effusion. No hypermetabolic

[page 8 of 9]
[REDACTED]

lesions.

ESOPHAGUS: There is no apparent esophageal wall thickening. No hypermetabolic esophageal lesions are seen.

PULMONARY: No developing pulmonary nodules. There is mild bilateral lower lobe atelectasis. No focal consolidation or pneumothorax. No hypermetabolic lesions are demonstrated.

A calcified nodule in the lingula is consistent with old granulomatous disease.

LYMPHATICS: There is no axillary, supraclavicular or mediastinal lymphadenopathy.

MUSCULOSKELETAL: No suspicious blastic or lytic osseous lesions.

ABDOMEN/PELVIS:

HEPATOBIILIARY: There is a stable arterially-enhancing lesion in segment 4A of the liver appreciated on image 106 on the axial slices. This lesion is stable in appearance and likely represents a flash filling hemangioma. Gallbladder is normal. No hypermetabolic liver lesions. The pancreas is normal.

GENITOURINARY: The adrenal glands are normal. No exophytic renal masses. No hypermetabolic lesions are seen. The urinary bladder is unremarkable. The prostate gland is prominent, but stable in size.

GASTROINTESTINAL: No bowel wall thickening or obstruction is seen. Diffuse colonic diverticulosis is noted. No evidence of acute diverticulitis. No hypermetabolic colonic lesions. The appendix is visualized in its entirety and is normal.

LYMPHATICS: The spleen is normal in size. No abdominal or pelvic lymphadenopathy. No hypermetabolic lymph nodes are seen within the abdomen or pelvis.

VASCULAR: The abdominal aorta is normal in course and caliber.

MUSCULOSKELETAL: No suspicious blastic or lytic osseous lesions. No hypermetabolic osseous lesions.

IMPRESSION:

1. No evidence of recurrent or metastatic disease is seen within the chest, abdomen, or pelvis.
2. Stable arterially-enhancing lesion in segment 4A of the liver, likely representing a flash filling hemangioma.
- [REDACTED]

Cc:

[REDACTED]

[page 9 of 9]
Scans on Order

OFF STUDY:

+948 Scan on [REDACTED] pet/ct questionnaire/iv contrast consent [REDACTED] +947

Result HistoryPET CT TUMOR IMAGING SKULL BASE TO MID THIGH (Order [REDACTED] on [REDACTED] Order Result
History Report +948**PACS Images**

Show images for PET CT TUMOR IMAGING SKULL BASE TO MID THIGH

Printable Result ReportOpen Hard Copy Result Report (Order [REDACTED] PET CT TUMOR IMAGING SKULL BASE TO MID
THIGH)

Imaging Information

Order Information

Order Name	Order ID	Order Date and Time	Order Date and	User Summary	Extended Time	Extended By
PET CT TUMOR IMAGING SKULL BASE TO MID THIGH [REDACTED]	[REDACTED]	[REDACTED]		Routine, Ancillary Performed		

Order Information

Order Date/Time	Release Date/Time	Start Date/Time	End Date/Time
[REDACTED] +753	[REDACTED] +947	[REDACTED] +947	None

Order Details

Frequency	Duration	Priority	Order Class
None	None	Routine	Ancillary Performed

Future Appointments

	Provider	Department	Center
[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]

Result Report Routing Report

Result Tracking

Order Information

PET CT TUMOR IMAGING SKULL BASE TO MID THIGH (Order [REDACTED] on [REDACTED] +947

Source: NCI Genomic Data Commons file a6f6fe2f-8ef7-4f53-9456-d35e31fe508c (ER0421 ER-AE6D Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).